Gene-level copy-number profile of tumor specimen TCGA-43-A56V-01A from TCGA case TCGA-43-A56V, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.5 years (22,475 days).
Specimen TCGA-43-A56V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4388801f-b7b6-477e-bb1c-51127408fb3c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-A56V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68bb66e1-440e-4229-b85e-a6188f372a38

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 30,649; copy number 2: 21,388; copy number 3: 6,141; copy number 4: 692; copy number 5: 505; copy number 6: 430.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-A56V-01A-11D-A26L-01): tumor purity 0.57, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,768 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–198,222,513, 1,803 genes, copy number 3–4 (broad region; genes not listed).
- chr4:55,853,648–57,724,655, 46 genes, copy number 3–4: EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1.
- chr5:58,198–24,850,971, 399 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr5:25,319,834–45,895,970, 303 genes, copy number 3 (broad region; genes not listed).
- chr8:35,080,592–42,207,709, 144 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 3–4 (broad region; genes not listed).
- chr9:30,773,464–35,405,338, 145 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr10:62,374,192–71,381,423, 143 genes, copy number 3–6 (within-gene range 1–6) (broad region; genes not listed).
- chr10:71,508,153–71,511,873, 1 gene, copy number 6: CDH23-AS1.
- chr12:66,767–34,249,958, 850 genes, copy number 4–6 (broad region; genes not listed).
- chr13:112,894,378–114,337,626, 53 genes, copy number 3 (within-gene range 2–3): MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 3 (broad region; genes not listed).
- chr16:20,028,239–20,925,006, 29 genes, copy number 3: GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1.
- chr18:22,699,481–24,162,211, 30 genes, copy number 4: AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,218,404, 3 genes, copy number 4: RNA5SP452, Metazoa_SRP, RNU6-435P.

Autosomal genes at a single copy (total copy number 1): 28,271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
